Somatic mutation profile of tumor specimen TCGA-CN-A63U-01A (aliquot TCGA-CN-A63U-01A-11D-A30E-08) from TCGA case TCGA-CN-A63U, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 50.0 years (18,272 days).
Specimen TCGA-CN-A63U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36a9c70f-c879-420d-a28d-e10659b9c21b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-A63U-10A (Blood Derived Normal), aliquot TCGA-CN-A63U-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8328a653-7cc9-4d25-a65d-ab5a6eaa9a85

The open-access MAF lists 575 somatic variants for this specimen: 438 protein-altering or splice-affecting, 123 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 367, Silent 123, Nonsense Mutation 29, Frame Shift Del 18, Splice Site 11, Frame Shift Ins 7, RNA 6, Splice Region 4, Intron 3, 3'UTR 3, In Frame Del 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTA2 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.965); catalogued as rs112602953, CM075975, COSV56518008; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL4A3 | c.172G>A p.G58S | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs184730597, CM1414109, COSV67413256; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- FBN1 | c.7082C>A p.S2361* | Nonsense Mutation (SNP) | VAF 23/57 reads (40%) | catalogued as rs397515844, CM145797, COSV100355430, COSV57313152; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs121917918, CM044039, COSV100320807; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.673-2A>T p.X225_splice | Splice Site (SNP) | VAF 95/115 reads (83%) | hotspot (GDC flag); catalogued as CS109519, COSV52669186, COSV52682653, COSV52687702; called by muse, mutect2, varscan2
- ABCA8 | c.3895G>A p.D1299N | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.906); catalogued as COSV99286057; called by muse, mutect2, varscan2
- ABCA8 | c.1103C>A p.A368D | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99286058; called by muse, mutect2, varscan2
- ABCC5 | c.1092C>A p.Y364* | Nonsense Mutation (SNP) | VAF 43/109 reads (39%) | catalogued as rs780142118, COSV99657029; called by muse, mutect2, varscan2
- ABHD12 | c.454G>T p.A152S | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV100194521; called by muse, mutect2, varscan2
- ABL1 | c.2977G>C p.A993P | Missense Mutation (SNP) | VAF 46/83 reads (55%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); catalogued as COSV100584137; called by muse, mutect2, varscan2
- ADAM22 | c.1176T>A p.C392* | Nonsense Mutation (SNP) | VAF 22/54 reads (41%) | catalogued as COSV99717257; called by muse, mutect2, varscan2
- ADAM29 | c.1728C>A p.F576L | Missense Mutation (SNP) | VAF 77/137 reads (56%) | SIFT tolerated (0.29); PolyPhen benign (0.096); catalogued as COSV100822047; called by muse, mutect2, varscan2
- ADAMTS10 | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.246); catalogued as COSV99547031; called by muse, mutect2, varscan2
- ADAMTS12 | c.3776C>A p.P1259H | Missense Mutation (SNP) | VAF 37/353 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.088); catalogued as COSV100711124; called by muse, mutect2, varscan2
- ADAMTS16 | c.3076C>A p.P1026T | Missense Mutation (SNP) | VAF 61/91 reads (67%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as rs375182504, COSV56997238; called by muse, mutect2, varscan2
- ADAMTS3 | c.2504A>T p.N835I | Missense Mutation (SNP) | VAF 55/146 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as COSV99711296; called by muse, mutect2, varscan2
- ADGRL4 | c.919C>A p.P307T | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.045); catalogued as COSV100876091; called by muse, mutect2, varscan2
- ADGRL4 | c.161C>A p.T54K | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.033); catalogued as rs201020837, COSV100876092; called by muse, mutect2, varscan2
- AEBP1 | c.907G>T p.G303C | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.67); catalogued as COSV99788855; called by muse, mutect2, varscan2
- AFF1 | c.1300G>T p.D434Y | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100320733; called by muse, mutect2, varscan2
- AGAP3 | c.767A>T p.Q256L (on ENST00000622464; = p.Q292L on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/148 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.31); catalogued as COSV100103826; called by muse, mutect2, varscan2
- AHDC1 | c.3514C>G p.Q1172E | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.731); catalogued as COSV99899424; called by muse, mutect2, varscan2
- AK5 | c.206C>A p.P69Q (on ENST00000354567 / NM_174858.3; = p.P43Q on NM_012093.4) | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100481503; called by muse, mutect2, varscan2
- AKT3 | c.434T>A p.M145K | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as COSV99795679; called by muse, mutect2, varscan2
- AL031777.2 | c.465G>T p.W155C | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT deleterious, low confidence (0.01); catalogued as COSV61912547; called by muse, mutect2, varscan2
- ANGEL2 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64737005; called by muse, mutect2, varscan2
- ANK1 | c.2842C>A p.R948S | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55889703, COSV99225589; called by muse, mutect2, varscan2
- ANKDD1A | c.508G>T p.G170W | Missense Mutation (SNP) | VAF 54/175 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201127218, COSV100132697; called by muse, mutect2, varscan2
- ANKRD27 | c.1964C>T p.S655L | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100042899; called by muse, mutect2
- ANO2 | c.112G>T p.G38C (on ENST00000356134 / NM_001278597.3; = p.G42C on NM_001278596.3) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.424); catalogued as rs750677510, COSV59034199; called by muse, mutect2, varscan2
- AQP9 | c.52T>A p.L18M | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as COSV99582978; called by muse, mutect2, varscan2
- ARHGAP15 | c.165+1G>C p.X55_splice | Splice Site (SNP) | VAF 22/70 reads (31%) | catalogued as COSV99711398; called by muse, mutect2, varscan2
- ARHGEF28 | c.3255G>T p.R1085S | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs572905410, COSV99709290; called by muse, mutect2, varscan2
- ARMC6 | c.1103G>T p.G368V (on ENST00000392336; = p.G343V on NM_033415.4) | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99523066; called by muse, mutect2, varscan2
- ASPDH | c.536C>G p.P179R (on ENST00000389208 / NM_001114598.2; = p.P74R on NM_001024656.3) | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100975948; called by muse, mutect2, varscan2
- ASTN1 | c.3285G>T p.M1095I | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.679); catalogued as COSV100707125; called by muse, mutect2, varscan2
- ASTN2 | c.1055T>C p.M352T | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.599); catalogued as rs758982548, COSV100528263; called by muse, mutect2, varscan2
- ASXL3 | c.3179G>C p.R1060P | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99323028, COSV99325240; called by muse, mutect2, varscan2
- ATG2B | c.3058G>T p.E1020* | Nonsense Mutation (SNP) | VAF 22/26 reads (85%) | catalogued as COSV100738072, COSV63425623; called by muse, mutect2, varscan2
- ATP13A4 | c.2027G>T p.R676M | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV55073959, COSV99794662; called by muse, mutect2, varscan2
- ATP8A2 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV99682415; called by muse, mutect2, varscan2
- AURKC | c.248G>T p.G83V (on ENST00000302804 / NM_001015878.2; = p.G49V on NM_003160.3) | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.519); catalogued as COSV100248748; called by muse, mutect2, varscan2
- AVPR1A | c.590T>C p.V197A | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV100146864; called by muse, mutect2, varscan2
- BBS4 | c.910T>C p.W304R | Missense Mutation (SNP) | VAF 19/139 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs751453946, COSV99166467; called by muse, mutect2, varscan2
- BHLHE22 | c.792G>C p.E264D | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.262); catalogued as COSV100417807; called by muse, mutect2, varscan2
- BRINP1 | c.1601G>T p.R534L | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV56307462, COSV99775837; called by muse, mutect2, varscan2
- BRINP2 | c.986C>T p.T329I | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100838144; called by muse, mutect2, varscan2
- C12orf40 | c.1286T>C p.M429T | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV100210212; called by muse, mutect2, varscan2
- C19orf54 | c.955C>T p.R319W | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs184492176, COSV99648819; called by muse, mutect2, varscan2
- C2orf76 | c.115A>G p.I39V | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as rs1041842487, COSV100601721; called by muse, mutect2, varscan2
- C9orf135 | c.665C>T p.T222I | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as rs1156885024, COSV101019885; called by muse, mutect2, varscan2
- CABP4 | c.539G>C p.R180P | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100351553; called by muse, mutect2, varscan2
- CACNG8 | c.424G>C p.G142R | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54415698, COSV99554878, COSV99555036; called by muse, mutect2, varscan2
- CALCRL | c.866A>C p.H289P | Missense Mutation (SNP) | VAF 80/201 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as COSV101130984; called by muse, mutect2, varscan2
- CAMTA2 | c.1123T>G p.F375V | Missense Mutation (SNP) | VAF 58/110 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as COSV100772653; called by muse, mutect2, varscan2
- CAPN13 | c.1406T>G p.F469C | Missense Mutation (SNP) | VAF 282/406 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99700346; called by muse, mutect2, varscan2
- CAPN9 | c.579C>G p.I193M | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.022); catalogued as COSV99680563; called by muse, mutect2, varscan2
- CASP2 | c.759G>C p.E253D | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.047); catalogued as COSV100131037, COSV60083723; called by muse, mutect2, varscan2
- CATSPERB | c.2066A>T p.N689I | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV99831384; called by muse, mutect2, varscan2
- CATSPERD | c.1883C>T p.P628L | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs778837999, COSV100486836; called by muse, mutect2, varscan2
- CBWD5 | c.13G>A p.V5I | Missense Mutation (SNP) | VAF 67/236 reads (28%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as COSV101070724; called by muse, mutect2, varscan2
- CBX5 | c.372A>T p.E124D | Missense Mutation (SNP) | VAF 57/204 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.649); catalogued as COSV99267689; called by muse, mutect2, varscan2
- CCDC112 | c.905A>G p.K302R | Missense Mutation (SNP) | VAF 53/93 reads (57%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as COSV101100467; called by muse, mutect2, varscan2
- CCDC114 | c.1032G>T p.K344N | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100196824; called by muse, mutect2, varscan2
- CCDC178 | c.2220A>T p.K740N (on ENST00000383096 / NM_001105528.3; = p.K702N on NM_198995.3) | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV100285175; called by muse, mutect2, varscan2
- CCL1 | c.157A>G p.T53A | Missense Mutation (SNP) | VAF 105/255 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV99861751; called by muse, mutect2, varscan2
- CCNB3 | c.1623G>T p.E541D | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as COSV99328628, COSV99329236; called by muse, mutect2, varscan2
- CCNB3 | c.2045A>G p.H682R | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.36); PolyPhen benign (0.046); catalogued as COSV99329237; called by muse, mutect2, varscan2
- CD300E | c.545T>C p.L182P | Missense Mutation (SNP) | VAF 74/180 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100151332; called by muse, mutect2, varscan2
- CDH12 | c.502A>T p.T168S | Missense Mutation (SNP) | VAF 32/225 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101202753; called by muse, mutect2, varscan2
- CDHR1 | c.454A>T p.S152C | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100258971; called by muse, mutect2, varscan2
- CEMIP2 | c.2869G>T p.V957L | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.222); catalogued as COSV100987123; called by muse, mutect2, varscan2
- CENPE | c.4611A>G p.I1537M | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.215); catalogued as COSV99478199; called by muse, mutect2, varscan2
- CEP350 | c.5889G>T p.Q1963H | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV100854851; called by muse, mutect2, varscan2
- CEP70 | c.1634G>T p.G545V | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99389279; called by muse, mutect2, varscan2
- CFAP53 | c.72A>G p.R24= | Splice Region (SNP) | VAF 18/39 reads (46%) | catalogued as COSV101274996; called by muse, mutect2, varscan2
- CFAP54 | c.7043C>T p.T2348I | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.074); catalogued as rs770038088, COSV100733227; called by muse, mutect2, varscan2
- CFAP92 | c.148C>A p.R50S | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.045); catalogued as COSV99414639; called by muse, mutect2, varscan2
- CIAO1 | c.815G>T p.G272V | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99720446; called by muse, mutect2, varscan2
- CLINT1 | c.1171G>T p.E391* | Nonsense Mutation (SNP) | VAF 38/64 reads (59%) | catalogued as COSV99754200; called by muse, mutect2, varscan2
- CLMN | c.2337C>A p.S779R | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV100112487; called by muse, mutect2, varscan2
- CLTC | c.2799T>G p.V933= | Splice Region (SNP) | VAF 20/54 reads (37%) | catalogued as COSV99292430; called by muse, mutect2, varscan2
- CMTM7 | c.238G>C p.V80L | Missense Mutation (SNP) | VAF 74/125 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100569962; called by muse, mutect2, varscan2
- COL11A2 | c.401C>G p.P134R | Missense Mutation (SNP) | VAF 61/221 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.365); catalogued as COSV100554154; called by muse, mutect2, varscan2
- COL14A1 | c.3758C>T p.P1253L | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99919547; called by muse, mutect2, varscan2
- COL22A1 | c.2700G>T p.P900= | Splice Region (SNP) | VAF 47/112 reads (42%) | catalogued as COSV100278875; called by muse, mutect2, varscan2
- COL24A1 | c.1141G>T p.D381Y | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as COSV100993476; called by muse, mutect2, varscan2
- COL9A1 | c.2690T>A p.L897H | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.975); catalogued as COSV100294933; called by muse, mutect2, varscan2
- COQ8B | c.33del p.T12Pfs*64 | Frame Shift Del (DEL) | VAF 40/108 reads (37%) | catalogued as COSV54574978; called by mutect2, pindel, varscan2
- CPNE5 | c.647A>T p.H216L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV99782869; called by muse, varscan2
- CPNE5 | c.646C>A p.H216N | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV99782872; called by muse, mutect2, varscan2
- CPO | c.803A>G p.N268S | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as COSV99786530; called by muse, mutect2, varscan2
- CPPED1 | c.375C>A p.S125R | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as COSV99903267; called by muse, mutect2, varscan2
- CPXM2 | c.2266G>T p.G756W | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV53870089; called by muse, mutect2, varscan2
- CRB1 | c.2848G>A p.A950T | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.638); catalogued as COSV100957926; called by muse, mutect2, varscan2
- CREB3L3 | c.83T>C p.L28P | Missense Mutation (SNP) | VAF 58/186 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99314222; called by muse, mutect2, varscan2
- CRHR2 | c.969C>A p.Y323* | Nonsense Mutation (SNP) | VAF 103/198 reads (52%) | catalogued as COSV100530051; called by muse, mutect2, varscan2
- CSMD1 | c.8234C>G p.P2745R (on ENST00000520002; = p.P2744R on NM_033225.6) | Missense Mutation (SNP) | VAF 55/155 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1296018102, COSV100149293; called by muse, mutect2, varscan2
- CTC1 | c.44G>T p.W15L | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100236514; called by muse, mutect2, varscan2
- CUBN | c.3734C>A p.P1245H | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100912879; called by muse, mutect2, varscan2
- CYP4F12 | c.250T>C p.Y84H | Missense Mutation (SNP) | VAF 69/225 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.249); catalogued as COSV100215896; called by muse, mutect2, varscan2
- CYP4Z1 | c.490C>T p.L164= | Splice Region (SNP) | VAF 43/87 reads (49%) | catalogued as COSV100497777; called by muse, mutect2, varscan2
- CYTIP | c.308G>T p.C103F | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as COSV99938773; called by muse, mutect2, varscan2
- DAAM2 | c.268G>T p.D90Y | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51309337, COSV99225941; called by muse, mutect2, varscan2
- DCAF1 | c.2306G>C p.S769T | Missense Mutation (SNP) | VAF 58/96 reads (60%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs782701779, COSV100244529; called by muse, mutect2, varscan2
- DGKI | c.2569A>G p.M857V | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99935175; called by muse, mutect2, varscan2
- DGLUCY | c.1192A>C p.T398P | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); catalogued as rs1408701440, COSV99824374; called by muse, mutect2, varscan2
- DLC1 | c.2952G>T p.R984S (on ENST00000276297 / NM_001348081.2; = p.R547S on NM_006094.5) | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as COSV52318927, COSV99363600; called by muse, mutect2, varscan2
- DNAH17 | c.7784C>T p.P2595L | Missense Mutation (SNP) | VAF 100/213 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101102583; called by muse, mutect2, varscan2
- DNM3 | c.2167C>A p.Q723K (on ENST00000355305 / NM_001350206.2; = p.Q717K on NM_015569.5) | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.492); catalogued as COSV100798370; called by muse, mutect2, varscan2
- DNMBP | c.1362A>T p.R454S | Missense Mutation (SNP) | VAF 82/135 reads (61%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.01); catalogued as COSV100143916; called by muse, mutect2, varscan2
- DOT1L | c.1288C>T p.Q430* | Nonsense Mutation (SNP) | VAF 32/124 reads (26%) | catalogued as COSV67108996; called by muse, mutect2, varscan2
- DOT1L | c.2119A>G p.M707V | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as rs780948550, COSV101288701; called by muse, mutect2, varscan2
- DSCAML1 | c.1593C>A p.N531K (on ENST00000321322; = p.N471K on NM_020693.4) | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.982); catalogued as COSV100356237; called by muse, mutect2, varscan2
- EIF3E | c.35A>C p.H12P | Missense Mutation (SNP) | VAF 67/137 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99623249; called by muse, mutect2, varscan2
- ELAPOR2 | c.1594-1G>T p.X532_splice (on ENST00000450689 / NM_001142749.3; = p.X365_splice on NM_152748.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 7/27 reads (26%) | catalogued as COSV99788949; called by muse, mutect2, varscan2
- ENO2 | c.1159G>C p.G387R | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV57544988, COSV99980337; called by muse, mutect2, varscan2
- ENTPD1 | c.1342G>C p.A448P | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100967583; called by muse, mutect2
- EPB41 | c.947G>A p.G316E (on ENST00000343067 / NM_001166005.2; = p.G107E on NM_004437.4) | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100548825; called by muse, mutect2, varscan2
- EPHA3 | c.1045C>A p.L349M | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.837); catalogued as COSV100345959; called by muse, mutect2, varscan2
- EPHA3 | c.1764A>T p.L588F | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0.08); catalogued as COSV100345967; called by muse, mutect2, varscan2
- ERICH3 | c.46C>A p.L16I | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100444666, COSV58599479; called by muse, mutect2, varscan2
- ERMAP | c.847C>G p.L283V | Missense Mutation (SNP) | VAF 75/152 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100072285; called by muse, mutect2, varscan2
- ESRRB | c.855C>G p.I285M | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV99835377; called by muse, mutect2, varscan2
- F5 | c.5134G>A p.A1712T | Missense Mutation (SNP) | VAF 103/187 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs1447393750, COSV100889139; called by muse, mutect2, varscan2
- FAAH2 | c.311A>T p.D104V | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1209878024, COSV100887350; called by muse, mutect2, varscan2
- FAM184A | c.2634C>A p.H878Q | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.72); catalogued as COSV100137939; called by muse, mutect2, varscan2
- FAM47B | c.1276G>T p.E426* | Nonsense Mutation (SNP) | VAF 40/62 reads (65%) | catalogued as COSV100264384; called by muse, mutect2, varscan2
- FAT2 | c.9649G>T p.V3217L | Missense Mutation (SNP) | VAF 54/79 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as rs537648951, COSV99943231; called by muse, mutect2, varscan2
- FAT3 | c.13031C>A p.S4344* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as COSV99035555; called by muse, mutect2, varscan2
- FAT4 | c.14500G>T p.G4834C | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.804); catalogued as COSV100628941; called by muse, mutect2, varscan2
- FBN1 | c.8350C>G p.L2784V | Missense Mutation (SNP) | VAF 60/153 reads (39%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.967); catalogued as COSV100355427; called by muse, mutect2, varscan2
- FCGR3A | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 101/726 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1445330608, COSV100914670; called by muse, varscan2
- FCGR3B | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 79/219 reads (36%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1487070772, COSV99670573; called by muse, mutect2, varscan2
- FER1L6 | c.2473G>A p.V825I | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs774388348, COSV101205938; called by muse, mutect2, varscan2
- FEZF1 | c.1185C>A p.N395K | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV100484501, COSV100484582; called by muse, mutect2, varscan2
- FLG2 | c.3017C>G p.S1006* | Nonsense Mutation (SNP) | VAF 213/478 reads (45%) | catalogued as COSV101165933; called by muse, mutect2, varscan2
- FLRT2 | c.1771G>T p.A591S | Missense Mutation (SNP) | VAF 88/236 reads (37%) | SIFT tolerated (0.73); PolyPhen benign (0.12); catalogued as COSV100420526; called by muse, mutect2, varscan2
- FOS | c.498A>C p.Q166H | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100338498; called by muse, mutect2, varscan2
- FRMD3 | c.1126A>T p.N376Y | Missense Mutation (SNP) | VAF 54/108 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as COSV100418818; called by muse, mutect2, varscan2
- FRY | c.6434T>A p.V2145D | Missense Mutation (SNP) | VAF 43/83 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100969391; called by muse, mutect2, varscan2
- FYB2 | c.941T>G p.L314R | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.605); catalogued as rs1238257271, COSV100599591; called by muse, mutect2, varscan2
- FZD10 | c.1259T>A p.L420Q | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99969468; called by muse, mutect2, varscan2
- GDNF | c.445T>C p.C149R | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100427481; called by muse, mutect2, varscan2
- GFRAL | c.869A>G p.Q290R | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as rs377010138; called by muse, mutect2, varscan2
- GIT1 | c.1363C>T p.R455W | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs538711253, COSV99838114; called by muse, mutect2, varscan2
- GLDC | c.1717T>C p.W573R | Missense Mutation (SNP) | VAF 43/62 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV58678711; called by muse, mutect2, varscan2
- GLI2 | c.4186G>C p.A1396P (on ENST00000361492 / NM_001374353.1; = p.A1413P on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV100083417, COSV58043175; called by muse, mutect2, varscan2
- GLUL | c.421G>T p.G141W | Missense Mutation (SNP) | VAF 43/292 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100092050; called by muse, mutect2, varscan2
- GNA14 | c.593+1G>T p.X198_splice | Splice Site (SNP) | VAF 49/116 reads (42%) | catalogued as COSV100503110; called by muse, mutect2, varscan2
- GNLY | c.95C>A p.A32E | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.13); catalogued as COSV99808951; called by muse, mutect2, varscan2
- GPC6 | c.217G>T p.D73Y | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV100989194; called by muse, mutect2, varscan2
- GRAMD1B | c.907C>A p.P303T | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as rs373808855, COSV100454832; called by muse, mutect2, varscan2
- GRIN2A | c.1318G>A p.V440I | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs758815434, COSV100410149; called by muse, mutect2, varscan2
- GRM1 | c.3380A>T p.E1127V | Missense Mutation (SNP) | VAF 67/168 reads (40%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.087); catalogued as COSV99266737; called by muse, mutect2, varscan2
- GRM3 | c.854T>C p.I285T | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV100862603; called by muse, mutect2, varscan2
- GRM3 | c.2509C>A p.H837N | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.624); catalogued as COSV100862604; called by muse, mutect2, varscan2
- GRM7 | c.952T>G p.S318A | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100736966; called by muse, mutect2, varscan2
- GSG1L | c.885G>T p.E295D (on ENST00000447459 / NM_001109763.2; = p.E140D on NM_144675.2) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.264); catalogued as COSV101093764; called by muse, mutect2, varscan2
- H2BC3 | c.62A>T p.K21M | Missense Mutation (SNP) | VAF 72/196 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.398); catalogued as COSV63551252; called by muse, mutect2, varscan2
- HAPLN1 | c.576C>G p.D192E | Missense Mutation (SNP) | VAF 44/70 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs767345569, COSV99164994; called by muse, mutect2, varscan2
- HBG2 | c.315+1G>T p.X105_splice | Splice Site (SNP) | VAF 31/89 reads (35%) | catalogued as COSV100400608, COSV100400648; called by muse, mutect2, varscan2
- HECTD2 | c.495A>C p.L165F | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); catalogued as COSV99978662; called by muse, mutect2, varscan2
- HIVEP3 | c.3421C>T p.P1141S | Missense Mutation (SNP) | VAF 51/184 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs768863050, COSV99911925, COSV99912943; called by muse, mutect2, varscan2
- HLX | c.547T>C p.S183P | Missense Mutation (SNP) | VAF 81/120 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100854556; called by muse, mutect2, varscan2
- IFIT1 | c.1174A>G p.K392E | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as COSV100878720; called by muse, mutect2, varscan2
- IFRD1 | c.788A>T p.K263M | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.218); catalogued as COSV99134033; called by muse, mutect2, varscan2
- IGLV8-61 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.901); catalogued as rs758470753, COSV101135139; called by muse, mutect2
- IMPG2 | c.2984A>G p.N995S | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99515722; called by muse, mutect2, varscan2
- IQGAP2 | c.331G>C p.D111H | Missense Mutation (SNP) | VAF 49/82 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99167430; called by muse, mutect2, varscan2
- ITGAX | c.1649G>A p.R550Q | Missense Mutation (SNP) | VAF 92/272 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.027); catalogued as rs201067451, COSV51648488; called by muse, mutect2, varscan2
- ITPR1 | c.5228G>A p.R1743H (on ENST00000354582; = p.R1688H on NM_002222.7) | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs767110471, COSV100231699; called by muse, mutect2, varscan2
- KCNA6 | c.332A>G p.N111S | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.289); catalogued as rs758200741, COSV99768709; called by muse, mutect2, varscan2
- KCNE4 | c.487G>C p.A163P | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.64); catalogued as COSV99918998; called by muse, mutect2, varscan2
- KCNH8 | c.3113C>T p.S1038L | Missense Mutation (SNP) | VAF 71/123 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs754806004, COSV60456690; called by muse, mutect2, varscan2
- KCNJ3 | c.1447A>G p.R483G | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.202); catalogued as COSV99715959; called by muse, mutect2, varscan2
- KCNT2 | c.880C>A p.H294N | Missense Mutation (SNP) | VAF 53/83 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as COSV99654425; called by muse, mutect2, varscan2
- KCTD8 | c.370T>A p.F124I | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100759645; called by muse, mutect2, varscan2
- KLHL1 | c.661C>G p.R221G | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); catalogued as COSV100917474, COSV64769679; called by muse, mutect2, varscan2
- KLK13 | c.386A>G p.E129G | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV99335321; called by muse, mutect2, varscan2
- KLK15 | c.328C>A p.L110M | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100032773; called by muse, mutect2, varscan2
- KLRC1 | c.347G>A p.C116Y | Missense Mutation (SNP) | VAF 91/237 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100760835; called by muse, mutect2, varscan2
- KRT32 | c.953C>A p.T318K | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV56787472, COSV99863054; called by muse, mutect2, varscan2
- KRTAP10-5 | c.428C>A p.P143H | Missense Mutation (SNP) | VAF 115/353 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100551435, COSV100554113; called by muse, mutect2, varscan2
- KRTAP4-2 | c.257T>G p.F86C | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757060661, COSV66658422; called by muse, mutect2, varscan2
- LAMA2 | c.7565C>A p.S2522Y | Missense Mutation (SNP) | VAF 78/222 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.248); catalogued as COSV101370549, COSV70346721; called by muse, mutect2, varscan2
- LCA5 | c.1105C>G p.Q369E | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100878302, COSV63973478; called by muse, mutect2, varscan2
- LENG8 | c.1926G>T p.Q642H | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100418097; called by muse, varscan2
- LHCGR | c.1940G>C p.R647P | Missense Mutation (SNP) | VAF 55/177 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as rs559262616, COSV54293731, COSV99683806; called by muse, mutect2, varscan2
- LILRA2 | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.596); catalogued as COSV52190489; called by muse, mutect2, varscan2
- LILRB1 | c.1529G>C p.G510A (on ENST00000427581; = p.G460A on NM_006669.6) | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.209); catalogued as COSV100207380; called by muse, mutect2, varscan2
- LMNB2 | c.958C>T p.Q320* | Nonsense Mutation (SNP) | VAF 11/30 reads (37%) | catalogued as COSV100322255; called by muse, mutect2, varscan2
- LNPEP | c.1780A>T p.N594Y | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.041); catalogued as COSV99183543; called by muse, mutect2, varscan2
- LRFN1 | c.934G>T p.V312L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs1465399703, COSV99953023; called by muse, mutect2, varscan2
- LRP11 | c.1060G>T p.V354L | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as COSV99497817; called by muse, mutect2, varscan2
- LRP11 | c.1059G>A p.M353I | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV99497818; called by muse, mutect2, varscan2
- LRP12 | c.1732C>A p.L578M | Missense Mutation (SNP) | VAF 45/81 reads (56%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs745813370, COSV52627980, COSV99407877; called by muse, mutect2, varscan2
- LRP1B | c.10033G>T p.G3345* | Nonsense Mutation (SNP) | VAF 22/60 reads (37%) | catalogued as COSV101257783, COSV67189219, COSV67231331; called by muse, mutect2, varscan2
- LRP1B | c.8348G>T p.G2783V | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1264132340, COSV101257785, COSV101261481; called by muse, mutect2, varscan2
- LRP1B | c.2596G>T p.G866C | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63341836; called by muse, mutect2, varscan2
- LRP1B | c.661G>T p.G221* | Nonsense Mutation (SNP) | VAF 20/56 reads (36%) | catalogued as COSV101257789; called by muse, mutect2, varscan2
- LRRC15 | c.1066C>G p.L356V | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV100752763; called by muse, mutect2, varscan2
- LRRTM1 | c.688C>A p.P230T | Missense Mutation (SNP) | VAF 62/223 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV54444464, COSV99702664; called by muse, mutect2, varscan2
- LSM1 | c.383A>G p.D128G | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.077); catalogued as COSV100258410; called by muse, mutect2, varscan2
- LYZ | c.23G>C p.G8A | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.188); catalogued as COSV99720150; called by muse, mutect2, varscan2
- MAGEA10 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 41/56 reads (73%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV99726758; called by muse, mutect2, varscan2
- MAGEB6B | c.854C>G p.S285W | Missense Mutation (SNP) | VAF 75/106 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV69689955; called by muse, mutect2, varscan2
- MAGEC1 | c.2800A>G p.M934V | Missense Mutation (SNP) | VAF 118/167 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.22); catalogued as rs755920518, COSV99595852; called by muse, mutect2, varscan2
- MAGI2 | c.607A>G p.I203V | Missense Mutation (SNP) | VAF 58/279 reads (21%) | SIFT tolerated (0.9); PolyPhen benign (0.041); catalogued as COSV100834905; called by muse, mutect2, varscan2
- MARCHF6 | c.2308G>T p.A770S | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV99929807; called by muse, mutect2, varscan2
- MATN1 | c.643A>C p.K215Q | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.99); catalogued as COSV101056338; called by muse, mutect2, varscan2
- MCOLN1 | c.63del p.Y22Mfs*29 | Frame Shift Del (DEL) | VAF 17/67 reads (25%) | catalogued as COSV99900522; called by mutect2, pindel, varscan2
- MMP20 | c.1120C>A p.Q374K | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs1284173266, COSV99497772; called by muse, mutect2, varscan2
- MMP20 | c.884T>G p.L295R | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV99497773; called by muse, mutect2, varscan2
- MNDA | c.1082G>C p.C361S | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.496); catalogued as COSV100933355; called by muse, mutect2, varscan2
- MORC1 | c.710T>A p.F237Y | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99226475; called by muse, mutect2, varscan2
- MPEG1 | c.1684A>T p.S562C | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99915542; called by muse, mutect2, varscan2
- MPPED1 | c.225G>T p.M75I | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as COSV100501252, COSV100501259; called by muse, mutect2, varscan2
- MRGBP | c.261G>T p.M87I | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV100978284; called by muse, mutect2, varscan2
- MROH5 | c.1838T>A p.L613H | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101436018; called by muse, mutect2, varscan2
- MRPS35 | c.829G>T p.E277* | Nonsense Mutation (SNP) | VAF 40/128 reads (31%) | catalogued as COSV99317531; called by muse, mutect2, varscan2
- MRPS9 | c.14G>A p.C5Y | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.088); catalogued as COSV99306144; called by muse, mutect2, varscan2
- MS4A2 | c.378+1G>C p.X126_splice | Splice Site (SNP) | VAF 14/38 reads (37%) | catalogued as COSV54013741, COSV99627355; called by muse, mutect2, varscan2
- MSTO1 | c.785G>T p.G262V | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99824254; called by muse, mutect2, varscan2
- MUC16 | c.38351G>T p.R12784M | Missense Mutation (SNP) | VAF 87/215 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV101200166; called by muse, mutect2, varscan2
- MUC17 | c.9109C>T p.P3037S | Missense Mutation (SNP) | VAF 271/648 reads (42%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.857); catalogued as COSV100073766; called by muse, mutect2, varscan2
- MUC17 | c.13309G>A p.D4437N | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.78); PolyPhen benign (0.01); catalogued as COSV100073768; called by muse, mutect2, varscan2
- MYEF2 | c.1267G>T p.G423* | Nonsense Mutation (SNP) | VAF 182/529 reads (34%) | catalogued as COSV99981746; called by muse, mutect2, varscan2
- MYO7A | c.2358C>G p.N786K | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV101289164; called by muse, mutect2, varscan2
- MYOCD | c.1292C>T p.P431L | Missense Mutation (SNP) | VAF 128/257 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.221); catalogued as COSV58508868; called by muse, mutect2, varscan2
- MYORG | c.1888G>C p.G630R | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99898673; called by muse, mutect2, varscan2
- NALCN | c.754G>T p.G252* | Nonsense Mutation (SNP) | VAF 41/130 reads (32%) | catalogued as rs746396065, COSV51922940, COSV99215784; called by muse, mutect2, varscan2
- NBEA | c.3575G>C p.G1192A | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV100081280; called by muse, mutect2, varscan2
- NCAM2 | c.1058G>T p.R353L | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV53055679; called by muse, mutect2, varscan2
- NEK10 | c.757G>C p.E253Q | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV100411978; called by muse, mutect2, varscan2
- NHS | c.1669G>T p.E557* | Nonsense Mutation (SNP) | VAF 44/66 reads (67%) | catalogued as COSV101196695; called by muse, mutect2, varscan2
- NIPSNAP1 | c.239A>T p.K80M | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99331173; called by muse, mutect2, varscan2
- NLGN1 | c.1897G>T p.D633Y | Missense Mutation (SNP) | VAF 70/215 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.785); catalogued as COSV100849434; called by muse, mutect2, varscan2
- NLGN1 | c.2291T>C p.L764P | Missense Mutation (SNP) | VAF 63/173 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1405564926, COSV64351713; called by muse, mutect2, varscan2
- NLGN4Y | c.1360G>A p.V454M | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as rs769995669, COSV59300032; called by muse, mutect2, varscan2
- NLRP10 | c.1955dup p.N652Kfs*40 | Frame Shift Ins (INS) | VAF 16/47 reads (34%) | catalogued as rs1195340578; called by mutect2, pindel
- NLRP14 | c.821C>A p.A274E | Missense Mutation (SNP) | VAF 56/91 reads (62%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.759); catalogued as COSV100205097; called by muse, mutect2, varscan2
- NPAS4 | c.1784G>A p.R595Q | Missense Mutation (SNP) | VAF 86/221 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs1465581894, COSV60651474; called by muse, mutect2, varscan2
- NSD1 | c.4501G>T p.E1501* | Nonsense Mutation (SNP) | VAF 27/43 reads (63%) | catalogued as COSV100729354; called by muse, mutect2, varscan2
- NYAP1 | c.417del p.S140Afs*63 | Frame Shift Del (DEL) | VAF 15/40 reads (38%) | catalogued as rs1173074678; called by mutect2, pindel, varscan2
- NYAP2 | c.1310C>A p.P437H | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56002359, COSV99797061; called by muse, mutect2, varscan2
- NYNRIN | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.125); catalogued as COSV101230615; called by muse, mutect2, varscan2
- OCA2 | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.006); catalogued as COSV100668082, COSV62352806; called by muse, mutect2, varscan2
- OR13G1 | c.731T>A p.V244E | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100687315; called by muse, mutect2, varscan2
- OR14C36 | c.586A>G p.M196V | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs748052992, COSV100507565; called by muse, mutect2, varscan2
- OR2F2 | c.650C>A p.S217Y | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101283823; called by muse, mutect2, varscan2
- OR2T10 | c.19A>T p.T7S | Missense Mutation (SNP) | VAF 43/68 reads (63%) | SIFT tolerated (0.11); PolyPhen benign (0.176); catalogued as COSV100393730; called by muse, mutect2, varscan2
- OR2T2 | c.112G>C p.V38L | Missense Mutation (SNP) | VAF 108/350 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.388); catalogued as COSV100737691, COSV61618957; called by muse, mutect2, varscan2
- OR2W1 | c.168T>A p.H56Q | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV101013918; called by muse, mutect2, varscan2
- OR52N4 | c.920T>G p.I307R | Missense Mutation (SNP) | VAF 40/71 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as COSV100421690, COSV57892108; called by muse, mutect2, varscan2
- OR9A4 | c.904del p.R302Gfs*4 | Frame Shift Del (DEL) | VAF 31/97 reads (32%) | catalogued as COSV71886052; called by pindel, varscan2
- OR9Q1 | c.590T>A p.V197E | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV100110071; called by muse, mutect2, varscan2
- OTOA | c.1317G>T p.K439N (on ENST00000286149; = p.K425N on NM_144672.4) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV53766272, COSV99624834; called by muse, mutect2, varscan2
- PAGE3 | c.244G>T p.G82C | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.247); catalogued as rs1198105134, COSV100891997; called by muse, mutect2, varscan2
- PAK6 | c.1583A>G p.K528R | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99544615; called by muse, mutect2, varscan2
- PAPPA2 | c.614G>C p.R205P | Missense Mutation (SNP) | VAF 44/213 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV62772010; called by muse, mutect2, varscan2
- PARP1 | c.520C>A p.P174T | Missense Mutation (SNP) | VAF 60/110 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV100828595; called by muse, mutect2, varscan2
- PARP8 | c.1594G>C p.E532Q | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV99891789; called by muse, mutect2, varscan2
- PATJ | c.3670+1G>T p.X1224_splice | Splice Site (SNP) | VAF 21/64 reads (33%) | catalogued as COSV100334416, COSV57164037; called by muse, mutect2, varscan2
- PAX1 | c.943G>T p.A315S | Missense Mutation (SNP) | VAF 74/184 reads (40%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); catalogued as COSV101270323, COSV68271777; called by muse, varscan2
- PAX1 | c.1010T>A p.V337E | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as COSV101270324; called by muse, varscan2
- PBX2 | c.56G>C p.G19A | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV100900733; called by muse, mutect2
- PCDHB11 | c.1587C>A p.F529L | Missense Mutation (SNP) | VAF 108/177 reads (61%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.808); catalogued as COSV100697036; called by muse, mutect2, varscan2
- PCDHB11 | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 106/175 reads (61%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.226); catalogued as rs782123077, COSV61311634; called by muse, mutect2, varscan2
- PCDHGA6 | c.1668T>G p.N556K | Missense Mutation (SNP) | VAF 176/274 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1389189532, COSV99540066; called by muse, mutect2, varscan2
- PCLO | c.4589G>T p.R1530I | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.414); catalogued as rs1403544723, COSV61647580; called by muse, mutect2, varscan2
- PDCD7 | c.1016G>A p.C339Y | Missense Mutation (SNP) | VAF 64/237 reads (27%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.547); catalogued as COSV99200144; called by muse, mutect2, varscan2
- PDGFRA | c.1606G>A p.V536M | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1265135270, COSV57270592; called by muse, mutect2, varscan2
- PDZD2 | c.4563C>A p.S1521R | Missense Mutation (SNP) | VAF 39/60 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV99225405; called by muse, mutect2, varscan2
- PEG3 | c.2437A>G p.I813V | Missense Mutation (SNP) | VAF 73/172 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.088); catalogued as rs750063058, COSV99689284; called by muse, mutect2, varscan2
- PGBD2 | c.565A>C p.S189R | Missense Mutation (SNP) | VAF 39/265 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100252084; called by muse, mutect2, varscan2
- PHF3 | c.4815G>T p.L1605F | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.143); catalogued as COSV100013459; called by muse, mutect2, varscan2
- PID1 | c.740C>A p.S247Y (on ENST00000354069 / NM_001330156.1; = p.S245Y on NM_017933.5) | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV100819716, COSV62479684; called by muse, mutect2, varscan2
- PIGO | c.759C>G p.S253R | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs757584977, COSV99956743; called by muse, mutect2, varscan2
- PIP5K1B | c.1616A>G p.Y539C | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.19); catalogued as COSV99599079; called by muse, mutect2, varscan2
- PKLR | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV100712919; called by muse, mutect2, varscan2
- PLA2G4E | c.776C>A p.A259D | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as COSV101268590; called by muse, mutect2, varscan2
- PLCB1 | c.33G>T p.L11F | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV100571319; called by muse, mutect2, varscan2
- PLEKHA4 | c.1493A>G p.Q498R | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as COSV99612681; called by muse, mutect2, varscan2
- PMS1 | c.1159G>T p.V387F | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV100575684; called by muse, mutect2, varscan2
- PODN | c.1423C>A p.R475S (on ENST00000395871; = p.R427S on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as COSV100439652; called by muse, mutect2, varscan2
- POLE | c.1163G>T p.G388V | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100267103; called by muse, mutect2, varscan2
- PON3 | c.599G>C p.R200P | Missense Mutation (SNP) | VAF 58/241 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV55699690, COSV99672549; called by muse, mutect2, varscan2
- POTEF | c.191G>T p.W64L | Missense Mutation (SNP) | VAF 175/479 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.307); catalogued as COSV100664867; called by muse, mutect2, varscan2
- POU2F3 | c.1068+1G>T p.X356_splice | Splice Site (SNP) | VAF 25/59 reads (42%) | catalogued as COSV99501205; called by muse, mutect2, varscan2
- PPP1R9A | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.149); catalogued as COSV99196001; called by muse, mutect2, varscan2
- PRAME | c.938T>G p.L313R | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101287103; called by muse, mutect2, varscan2
- PRDM9 | c.29G>T p.S10I | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.338); catalogued as COSV57005646, COSV99689793; called by muse, mutect2, varscan2
- PRKCA | c.343T>G p.C115G | Missense Mutation (SNP) | VAF 102/227 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99435007; called by muse, mutect2, varscan2
- PRLR | c.1286C>A p.S429Y | Missense Mutation (SNP) | VAF 30/270 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99184459; called by muse, mutect2, varscan2
- PRLR | c.1285T>C p.S429P | Missense Mutation (SNP) | VAF 31/273 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.029); catalogued as COSV99184461; called by muse, mutect2, varscan2
- PRUNE2 | c.6904A>C p.S2302R | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100944717; called by muse, mutect2, varscan2
- PSD3 | c.1540G>A p.V514M | Missense Mutation (SNP) | VAF 67/155 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as rs374109905; called by muse, mutect2, varscan2
- PSG8 | c.689C>A p.P230Q | Missense Mutation (SNP) | VAF 190/728 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs768349850, COSV100126319; called by muse, mutect2, varscan2
- PTPN14 | c.2377C>T p.R793W | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as rs780710386, COSV100872693; called by muse, mutect2, varscan2
- PTPRD | c.4676G>C p.R1559P | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100645160, COSV61975664; called by muse, mutect2, varscan2
- PTPRD | c.2392C>T p.L798F | Missense Mutation (SNP) | VAF 57/103 reads (55%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV100645162, COSV61952994; called by muse, mutect2, varscan2
- R3HDM1 | c.1350T>A p.H450Q | Missense Mutation (SNP) | VAF 56/171 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.031); catalogued as COSV99926344; called by muse, mutect2, varscan2
- RAPGEF6 | c.4552G>A p.D1518N | Missense Mutation (SNP) | VAF 51/83 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.889); catalogued as COSV99726729; called by muse, mutect2, varscan2
- RASGRF1 | c.2737G>C p.A913P | Missense Mutation (SNP) | VAF 52/159 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV101174559; called by muse, mutect2, varscan2
- RBM47 | c.273C>A p.F91L | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.557); catalogued as COSV55942744, COSV99920941; called by muse, mutect2, varscan2
- REG1A | c.61C>A p.Q21K | Missense Mutation (SNP) | VAF 41/60 reads (68%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV52068819; called by muse, mutect2, varscan2
- RGS7 | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 18/102 reads (18%) | catalogued as COSV100468261; called by muse, mutect2, varscan2
- RIMS2 | c.4321G>T p.D1441Y (on ENST00000666250 / NM_001348490.2; = p.D1012Y on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99170436; called by muse, mutect2, varscan2
- RIPOR1 | c.1106G>T p.R369L (on ENST00000379312 / NM_001193522.2; = p.R365L on NM_024519.4) | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.931); catalogued as COSV99243215; called by muse, mutect2, varscan2
- RNF10 | c.97G>T p.G33W | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as COSV100378738, COSV58043404; called by muse, mutect2, varscan2
- RNF144A | c.510-1G>A p.X170_splice | Splice Site (SNP) | VAF 53/70 reads (76%) | catalogued as COSV100305783; called by muse, mutect2, varscan2
- RNF150 | c.1185C>G p.I395M | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.044); catalogued as COSV100153606; called by muse, mutect2, varscan2
- ROCK2 | c.3305G>A p.R1102Q | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.707); catalogued as rs766071383, COSV59953089; called by muse, mutect2, varscan2
- ROS1 | c.642C>A p.S214R | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.401); catalogued as COSV100877186, COSV63854481; called by muse, mutect2, varscan2
- RTN4IP1 | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.393); catalogued as rs1170498036, COSV100954198; called by muse, mutect2, varscan2
- RYR2 | c.6079G>T p.G2027W | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100770971; called by muse, mutect2, varscan2
- SCN9A | c.3802G>A p.V1268I (on ENST00000303354; = p.V1257I on NM_002977.3) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.958); catalogued as COSV100313121; called by muse, mutect2
- SEPTIN14 | c.833A>G p.H278R | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101193353; called by muse, mutect2, varscan2
- SERBP1 | c.1039C>G p.P347A (on ENST00000370995 / NM_001018067.2; = p.P326A on NM_015640.4) | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.917); catalogued as COSV100769125; called by muse, mutect2, varscan2
- SERPINB6 | c.639G>T p.E213D (on ENST00000612421 / NM_001271823.2; = p.E194D on NM_004568.6) | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.029); catalogued as COSV100177524; called by muse, mutect2, varscan2
- SESTD1 | c.205G>T p.G69C | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV101468137; called by muse, mutect2, varscan2
- SFMBT2 | c.2567T>A p.L856Q | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100739181; called by muse, mutect2, varscan2
- SHD | c.922A>T p.S308C | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as COSV100010327; called by muse, mutect2, varscan2
- SHPRH | c.1157T>C p.L386P | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99262202; called by muse, mutect2, varscan2
- SKI | c.1351C>T p.Q451* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as COSV101049443; called by muse, varscan2
- SLC12A1 | c.1831T>C p.F611L | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV101118871; called by muse, mutect2, varscan2
- SLC12A7 | c.1127T>A p.L376Q | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.017); catalogued as COSV99370059; called by muse, mutect2, varscan2
- SLC13A3 | c.1640C>G p.T547R | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99286763; called by muse, mutect2, varscan2
- SLC14A2 | c.82C>A p.P28T | Missense Mutation (SNP) | VAF 50/76 reads (66%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV99675627; called by muse, mutect2, varscan2
- SLC30A10 | c.834C>A p.Y278* | Nonsense Mutation (SNP) | VAF 22/167 reads (13%) | catalogued as COSV100751527; called by muse, mutect2, varscan2
- SLC35F1 | c.760G>T p.G254C | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100837770; called by muse, mutect2, varscan2
- SLC35F1 | c.940_941insA p.L314Hfs*55 | Frame Shift Ins (INS) | VAF 118/388 reads (30%) | catalogued as COSV100837771; called by mutect2, pindel, varscan2
- SLC35F2 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 74/191 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.543); catalogued as COSV99758667, COSV99758683; called by muse, mutect2, varscan2
- SLC39A14 | c.785C>T p.S262L | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.052); catalogued as COSV99249826; called by muse, mutect2, varscan2
- SLC4A11 | c.971C>T p.S324F | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.603); catalogued as COSV101196020; called by muse, mutect2, varscan2
- SLC5A8 | c.530G>A p.C177Y | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101125323, COSV65987093; called by muse, mutect2, varscan2
- SLC6A19 | c.424A>T p.N142Y | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100443528; called by muse, mutect2, varscan2
- SLCO5A1 | c.662C>A p.P221H | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs762870502, COSV99480094, COSV99480242; called by muse, mutect2, varscan2
- SLITRK1 | c.1187T>A p.V396E | Missense Mutation (SNP) | VAF 86/295 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV100999980; called by muse, mutect2, varscan2
- SMC1B | c.2524A>C p.I842L | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100663296; called by muse, mutect2, varscan2
- SMO | c.2197G>T p.V733F | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.561); catalogued as COSV99976740; called by muse, mutect2
- SNAP25 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99654856; called by muse, mutect2, varscan2
- SNX7 | c.567G>C p.L189F | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100069142; called by muse, mutect2, varscan2
- SNX7 | c.863A>G p.Y288C | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.162); catalogued as COSV100069144; called by muse, mutect2, varscan2
- SPATA17 | c.611C>G p.P204R | Missense Mutation (SNP) | VAF 61/113 reads (54%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV100861186, COSV65121044; called by muse, mutect2, varscan2
- SPECC1 | c.3116T>A p.L1039Q | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99822183; called by muse, mutect2, varscan2
- SPEF2 | c.2850T>A p.H950Q | Missense Mutation (SNP) | VAF 44/68 reads (65%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV100607717; called by muse, mutect2, varscan2
- SPN | c.829T>C p.W277R | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1490973317, COSV100788816; called by muse, mutect2, varscan2
- SPOCD1 | c.1645G>A p.G549S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); catalogued as COSV99929987; called by muse, mutect2, varscan2
- SPTAN1 | c.2929G>T p.D977Y | Missense Mutation (SNP) | VAF 37/63 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63986566, COSV63991148; called by muse, mutect2, varscan2
- SPTSSB | c.13C>G p.R5G | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as COSV100780643, COSV63218959; called by muse, mutect2, varscan2
- ST3GAL5 | c.775A>G p.I259V (on ENST00000377332; = p.I299V on NM_003896.4) | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.071); catalogued as rs775050657, COSV100088490; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.582G>T p.Q194H | Missense Mutation (SNP) | VAF 50/193 reads (26%) | PolyPhen possibly damaging (0.863); catalogued as COSV100602803; called by muse, mutect2, varscan2
- STARD7 | c.645G>A p.W215* | Nonsense Mutation (SNP) | VAF 63/140 reads (45%) | catalogued as COSV100474749; called by muse, mutect2, varscan2
- STX4 | c.847A>G p.T283A | Missense Mutation (SNP) | VAF 110/289 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100572954; called by muse, mutect2, varscan2
- SYNE1 | c.26094+1G>T p.X8698_splice (on ENST00000367255 / NM_182961.4; = p.X8650_splice on NM_033071.3) | Splice Site (SNP) | VAF 28/103 reads (27%) | catalogued as COSV99567629; called by muse, mutect2, varscan2
- SYNE1 | c.16619T>A p.L5540* (on ENST00000367255 / NM_182961.4; = p.L5469* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 17/45 reads (38%) | catalogued as COSV99567631; called by muse, mutect2, varscan2
- SYNE1 | c.15871C>G p.P5291A (on ENST00000367255 / NM_182961.4; = p.P5220A on NM_033071.3) | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.79); PolyPhen benign (0.009); catalogued as COSV99567639; called by muse, mutect2, varscan2
- SYNE2 | c.6270G>T p.K2090N | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100647886; called by muse, mutect2, varscan2
- SYTL5 | c.2165G>A p.R722H | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs775058607, COSV52900311; called by muse, mutect2, varscan2
- TAF1L | c.2593C>A p.L865I | Missense Mutation (SNP) | VAF 66/197 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99644845; called by muse, mutect2, varscan2
- TBC1D24 | c.1526G>T p.G509V (on ENST00000646147 / NM_001199107.2; = p.G503V on NM_020705.3) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs796053406, COSV53546821; ClinVar: uncertain significance; called by muse, mutect2
- TBCK | c.1586G>A p.R529K (on ENST00000273980 / NM_001163436.4; = p.R466K on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV99912686; called by muse, mutect2, varscan2
- TDRD6 | c.1164G>T p.W388C | Missense Mutation (SNP) | VAF 56/154 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100287768; called by muse, mutect2, varscan2
- TENM1 | c.1817C>T p.T606I | Missense Mutation (SNP) | VAF 133/182 reads (73%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1358173270, COSV100950269; called by muse, mutect2, varscan2
- TG | c.1726del p.E576Nfs*20 | Frame Shift Del (DEL) | VAF 19/119 reads (16%) | catalogued as COSV55091239, COSV99603914; called by mutect2, pindel, varscan2
- TGIF1 | c.112C>G p.R38G (on ENST00000330513 / NM_001374396.1; = p.R58G on NM_003244.4) | Missense Mutation (SNP) | VAF 103/1754 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs749217690, COSV100394876; called by muse, mutect2
- TMEM175 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.793); catalogued as rs143946130; called by mutect2, varscan2
- TMEM176A | c.629T>A p.L210Q | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99133789; called by muse, mutect2, varscan2
- TMEM176B | c.103C>A p.Q35K | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.158); catalogued as rs756904639, COSV99133786; called by muse, mutect2, varscan2
- TNFRSF21 | c.1244G>A p.G415D | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57285587; called by muse, mutect2, varscan2
- TOP3B | c.1208del p.G403Vfs*79 | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | catalogued as rs1254041832; called by mutect2, pindel, varscan2
- TRAF6 | c.314G>A p.C105Y | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100777710; called by muse, mutect2, varscan2
- TRAV8-7 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1462782149; called by muse, mutect2, varscan2
- TRDN | c.1990G>A p.V664I | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.026); catalogued as rs756257644, COSV100522286; called by muse, mutect2, varscan2
- TRIB2 | c.1006G>T p.E336* | Nonsense Mutation (SNP) | VAF 38/108 reads (35%) | catalogued as COSV99331159; called by muse, mutect2, varscan2
- TRIM17 | c.346C>A p.P116T | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.989); catalogued as COSV99694751; called by muse, mutect2, varscan2
- TSSK2 | c.261C>G p.Y87* | Nonsense Mutation (SNP) | VAF 24/62 reads (39%) | catalogued as COSV99350972; called by muse, mutect2, varscan2
- TTBK1 | c.112A>T p.K38* | Nonsense Mutation (SNP) | VAF 32/72 reads (44%) | catalogued as COSV99444821; called by muse, mutect2, varscan2
- TTC7A | c.683G>A p.G228D | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.241); catalogued as rs1270829894, COSV99766536; called by muse, mutect2, varscan2
- TTN | c.89392A>G p.K29798E (on ENST00000591111; = p.K22374E on NM_003319.4) | Missense Mutation (SNP) | VAF 110/253 reads (43%) | PolyPhen possibly damaging (0.488); catalogued as COSV100617427; called by muse, mutect2, varscan2
- TTN | c.71052G>T p.W23684C (on ENST00000591111; = p.W16260C on NM_003319.4) | Missense Mutation (SNP) | VAF 41/92 reads (45%) | PolyPhen probably damaging (0.999); catalogued as rs746749916, COSV100617431, COSV60361135; called by muse, mutect2, varscan2
- U2AF1L4 | c.482+1G>A p.X161_splice (on ENST00000412391; = p.X122_splice on NM_001040425.3) | Splice Site (SNP) | VAF 20/93 reads (22%) | catalogued as rs372530599; called by muse, mutect2, varscan2
- UBN2 | c.2065A>T p.K689* | Nonsense Mutation (SNP) | VAF 8/46 reads (17%) | catalogued as COSV99944048; called by muse, mutect2, varscan2
- UGT1A4 | c.90G>T p.K30N | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.393); catalogued as rs760663679, COSV100530371, COSV100530651; called by muse, mutect2, varscan2
- UGT2A1 | c.1160C>A p.P387H | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99684472; called by muse, mutect2, varscan2
- UNC13C | c.3528G>T p.K1176N | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.158); catalogued as COSV52874359, COSV99518669; called by muse, mutect2, varscan2
- URB2 | c.778G>T p.D260Y | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV99271342; called by muse, mutect2
- USH2A | c.8524C>T p.Q2842* | Nonsense Mutation (SNP) | VAF 9/57 reads (16%) | catalogued as COSV100236710; called by muse, mutect2, varscan2
- USH2A | c.6254T>C p.I2085T | Missense Mutation (SNP) | VAF 60/93 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100236714; called by muse, mutect2, varscan2
- USP38 | c.1930G>T p.G644C | Missense Mutation (SNP) | VAF 120/354 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.796); catalogued as COSV100189298; called by muse, mutect2, varscan2
- UTRN | c.5410G>T p.E1804* | Nonsense Mutation (SNP) | VAF 5/14 reads (36%) | catalogued as COSV100839984; called by muse, mutect2
- VAV2 | c.338C>G p.S113W | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV100895865; called by muse, mutect2, varscan2
- VCAM1 | c.1297del p.D434Tfs*17 | Frame Shift Del (DEL) | VAF 30/92 reads (33%) | catalogued as COSV54117896, COSV99658215; called by mutect2, pindel, varscan2
- VTA1 | c.769A>G p.I257V | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs775531776, COSV100859217; called by muse, mutect2, varscan2
- VWA5A | c.1523C>A p.P508Q | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.076); catalogued as COSV100827889; called by muse, mutect2
- XIRP2 | c.72T>A p.S24R | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV99743888; called by muse, mutect2, varscan2
- YAF2 | c.308C>G p.P103R | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100586342; called by muse, mutect2
- ZC3H12C | c.2048C>G p.P683R | Missense Mutation (SNP) | VAF 112/410 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.296); catalogued as rs1243380628, COSV99585077; called by muse, mutect2, varscan2
- ZCCHC7 | c.1541A>G p.K514R | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV100383206; called by muse, mutect2, varscan2
- ZFHX4 | c.166C>A p.R56S | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.193); catalogued as COSV50478734, COSV99259381; called by muse, mutect2, varscan2
- ZFP36L2 | c.431dup p.G145Rfs*329 | Frame Shift Ins (INS) | VAF 28/50 reads (56%) | catalogued as rs1558428769; called by mutect2, pindel, varscan2
- ZIC4 | c.541C>A p.Q181K | Missense Mutation (SNP) | VAF 111/279 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV101268015; called by muse, mutect2, varscan2
- ZNF202 | c.355A>G p.T119A | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.89); catalogued as COSV100279066; called by muse, mutect2, varscan2
- ZNF226 | c.303G>T p.W101C | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV100335175; called by muse, mutect2, varscan2
- ZNF347 | c.413C>T p.T138I | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100498326; called by muse, mutect2, varscan2
- ZNF551 | c.1853G>A p.S618N | Missense Mutation (SNP) | VAF 71/159 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.158); catalogued as COSV99990040; called by muse, mutect2, varscan2
- ZNF566 | c.1219G>A p.D407N | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV101091451, COSV67573330; called by muse, mutect2, varscan2
- ZNF620 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 51/75 reads (68%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.528); catalogued as COSV100094090; called by muse, mutect2, varscan2
- ZNF682 | c.1307G>C p.R436P | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.763); catalogued as COSV100653279, COSV62065994; called by muse, mutect2, varscan2
- ZNF700 | c.1570C>G p.Q524E | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.246); catalogued as COSV99583580; called by muse, mutect2, varscan2
- ZNF71 | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs372176440, COSV100046012; called by muse, mutect2, varscan2
- ZNF804A | c.2461C>A p.P821T | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100168374; called by muse, mutect2, varscan2
- ZNF804B | c.3223G>C p.G1075R | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); catalogued as COSV100304249, COSV100306710; called by muse, mutect2, varscan2
- ZNF827 | c.777G>T p.K259N | Missense Mutation (SNP) | VAF 41/64 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101061443; called by muse, mutect2, varscan2
- ZNF836 | c.217G>T p.V73L | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV100441010; called by muse, mutect2, varscan2
- ZSCAN5B | c.1264C>A p.H422N | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as rs772396860, COSV100627988; called by muse, mutect2, varscan2
- ABCB1 | c.3768_3772del p.H1257Afs*31 | Frame Shift Del (DEL) | VAF 15/104 reads (14%) | called by mutect2, pindel, varscan2
- ADCK2 | c.440_460del p.K147_S153del | In Frame Del (DEL) | VAF 24/128 reads (19%) | called by mutect2, pindel, varscan2
- AHNAK | c.9267dup p.K3090Qfs*6 | Frame Shift Ins (INS) | VAF 123/461 reads (27%) | called by mutect2, pindel, varscan2
- AMPD1 | c.913del p.Q305Rfs*12 | Frame Shift Del (DEL) | VAF 18/109 reads (17%) | called by mutect2, pindel, varscan2
- CACNB2 | c.328del p.A110Qfs*51 (on ENST00000324631 / NM_201596.3; = p.A55Qfs*51 on NM_000724.4) | Frame Shift Del (DEL) | VAF 13/70 reads (19%) | called by mutect2, pindel, varscan2
- CD1E | c.110del p.F37Sfs*41 | Frame Shift Del (DEL) | VAF 27/152 reads (18%) | called by mutect2, pindel, varscan2
- CMIP | c.2192T>G p.L731R (on ENST00000537098 / NM_198390.2; = p.L637R on NM_030629.3) | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- CWC25 | c.1175T>C p.L392P | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EBF1 | c.1050del p.T351Pfs*27 | Frame Shift Del (DEL) | VAF 23/51 reads (45%) | called by mutect2, pindel, varscan2
- EEF2 | c.888dup p.I297Hfs*6 | Frame Shift Ins (INS) | VAF 57/225 reads (25%) | called by mutect2, pindel, varscan2
- HEPH | c.3255del p.R1086Efs*8 (on ENST00000343002; = p.R819Efs*8 on NM_014799.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 21/37 reads (57%) | called by mutect2, pindel, varscan2
- HIVEP3 | c.2780del p.P927Lfs*14 | Frame Shift Del (DEL) | VAF 53/153 reads (35%) | called by mutect2, pindel, varscan2
- HS3ST4 | c.1266dup p.D423Rfs*33 | Frame Shift Ins (INS) | VAF 11/34 reads (32%) | called by mutect2, pindel, varscan2
- IGHV1OR21-1 | c.109G>T p.V37L | Missense Mutation (SNP) | VAF 52/332 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- RAD54L2 | c.1919_1920del p.E640Afs*29 | Frame Shift Del (DEL) | VAF 23/54 reads (43%) | called by mutect2, pindel, varscan2
- SCN5A | c.5024del p.G1675Afs*112 (on ENST00000333535 / NM_198056.3; = p.G1674Afs*112 on NM_000335.5) | Frame Shift Del (DEL) | VAF 80/166 reads (48%) | called by mutect2, pindel, varscan2
- SHROOM4 | c.3328del p.E1110Rfs*71 | Frame Shift Del (DEL) | VAF 23/34 reads (68%) | called by mutect2, pindel*, varscan2
- TNIK | c.1634_1642del p.R545_S548delinsP | In Frame Del (DEL) | VAF 7/16 reads (44%) | called by mutect2, varscan2
- UNC5D | c.2504dup p.A836Rfs*31 | Frame Shift Ins (INS) | VAF 13/94 reads (14%) | called by mutect2, pindel, varscan2
- URB2 | c.477del p.R159Sfs*8 | Frame Shift Del (DEL) | VAF 14/84 reads (17%) | called by mutect2, pindel, varscan2
- ABCA8 | c.4449A>T p.A1483= | Silent (SNP) | VAF 35/105 reads (33%) | catalogued as COSV99286056; called by muse, mutect2, varscan2
- ADCYAP1 | c.331C>A p.R111= | Silent (SNP) | VAF 33/218 reads (15%) | catalogued as COSV99327522; called by muse, mutect2, varscan2
- ADGRF4 | c.675C>A p.L225= | Silent (SNP) | VAF 40/128 reads (31%) | catalogued as COSV99348513; called by muse, varscan2
- ADSS2 | c.516C>G p.S172= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV100836857; called by muse, mutect2, varscan2
- AGPAT4 | c.261G>A p.K87= | Silent (SNP) | VAF 35/86 reads (41%) | catalogued as COSV57247719; called by muse, mutect2, varscan2
- ANKRD24 | c.1422G>A p.Q474= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV99517648; called by muse, mutect2, varscan2
- APCDD1 | c.387C>A p.R129= | Silent (SNP) | VAF 46/126 reads (37%) | catalogued as COSV100789974; called by muse, mutect2, varscan2
- ATP9A | c.1836G>A p.Q612= | Silent (SNP) | VAF 163/442 reads (37%) | catalogued as COSV100125135; called by muse, mutect2, varscan2
- CATSPERD | c.2019C>A p.G673= | Silent (SNP) | VAF 43/113 reads (38%) | catalogued as COSV100486838; called by muse, mutect2, varscan2
- CCDC102B | c.330A>T p.R110= | Silent (SNP) | VAF 39/69 reads (57%) | catalogued as COSV100103795; called by muse, mutect2, varscan2
- CD1A | c.945A>T p.I315= | Silent (SNP) | VAF 57/235 reads (24%) | catalogued as COSV99192432; called by muse, mutect2, varscan2
- CDH11 | c.1062C>T p.I354= | Silent (SNP) | VAF 42/69 reads (61%) | catalogued as rs771089094, COSV51765224; called by muse, mutect2, varscan2
- CHERP | c.1248A>G p.P416= | Silent (SNP) | VAF 33/148 reads (22%) | catalogued as COSV99550314; called by muse, mutect2, varscan2
- CNKSR1 | c.24C>G p.T8= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV100836747; called by muse, mutect2, varscan2
- COL4A4 | c.2448G>A p.G816= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV100307032; called by muse, mutect2, varscan2
- COL6A3 | c.2220T>C p.R740= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV99798967; called by muse, mutect2, varscan2
- COPA | c.1393C>T p.L465= | Silent (SNP) | VAF 39/171 reads (23%) | catalogued as COSV99615916; called by muse, mutect2, varscan2
- CPA5 | c.1239C>A p.I413= | Silent (SNP) | VAF 46/187 reads (25%) | catalogued as COSV62569089, COSV62570525; called by muse, mutect2, varscan2
- CPM | c.870G>A p.E290= | Silent (SNP) | VAF 35/88 reads (40%) | catalogued as COSV100615116; called by muse, mutect2, varscan2
- CRHR1 | c.126G>A p.L42= | Silent (SNP) | VAF 33/64 reads (52%) | catalogued as rs538744624, COSV99523763; called by muse, mutect2, varscan2
- CSMD2 | c.1278C>T p.D426= | Silent (SNP) | VAF 37/159 reads (23%) | catalogued as COSV99591366; called by muse, mutect2, varscan2
- DENND2B | c.1509T>C p.D503= | Silent (SNP) | VAF 27/45 reads (60%) | catalogued as COSV100567554; called by muse, mutect2, varscan2
- DGKG | c.2151G>C p.G717= | Silent (SNP) | VAF 56/148 reads (38%) | catalogued as COSV53970365, COSV99403555; called by muse, mutect2, varscan2
- DGKI | c.1869A>T p.P623= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV99935180; called by muse, mutect2, varscan2
- DPY19L1 | c.1380A>G p.A460= | Silent (SNP) | VAF 32/65 reads (49%) | catalogued as rs376525655, COSV100204755; called by muse, mutect2, varscan2
- EEF1AKNMT | c.963G>T p.R321= (on ENST00000361735 / NM_015935.5; = p.R235= on NM_014955.3) | Silent (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- EPHA5 | c.1770C>A p.I590= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as COSV56628628, COSV99896015, COSV99899441; called by muse, mutect2, varscan2
- EPHA7 | c.1143C>A p.P381= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as COSV100993877; called by muse, mutect2, varscan2
- ERCC6 | c.2031G>C p.P677= | Silent (SNP) | VAF 36/81 reads (44%) | catalogued as COSV100875973; called by muse, mutect2, varscan2
- ESPL1 | c.1014G>A p.E338= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as COSV99229419; called by muse, mutect2, varscan2
- EVX2 | c.651C>T p.R217= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as COSV100420713, COSV57962839; called by muse, mutect2, varscan2
- F13B | c.726T>C p.H242= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as COSV100803321, COSV66374096; called by muse, mutect2, varscan2
- FAT4 | c.6330A>G p.G2110= | Silent (SNP) | VAF 68/194 reads (35%) | catalogued as COSV100628937; called by muse, mutect2, varscan2
- FAT4 | c.6624A>T p.T2208= | Silent (SNP) | VAF 47/169 reads (28%) | catalogued as COSV100628939; called by muse, mutect2, varscan2
- FILIP1 | c.963G>A p.L321= | Silent (SNP) | VAF 39/131 reads (30%) | catalogued as COSV99385121; called by muse, mutect2, varscan2
- GBA3 | c.846A>G p.P282= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs780179876, COSV101545527; called by muse, mutect2, varscan2
- GGT5 | c.822C>A p.P274= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as COSV54073035, COSV99571638; called by muse, mutect2
- GPR31 | c.144G>T p.P48= | Silent (SNP) | VAF 24/85 reads (28%) | catalogued as COSV100834146, COSV64762049; called by muse, mutect2, varscan2
- GPR39 | c.567C>A p.L189= | Silent (SNP) | VAF 39/95 reads (41%) | catalogued as COSV100257914; called by muse, mutect2, varscan2
- GRIK2 | c.732T>A p.A244= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as COSV100026902; called by muse, mutect2, varscan2
- HTATIP2 | c.492A>G p.V164= | Silent (SNP) | VAF 23/32 reads (72%) | catalogued as COSV101346161; called by muse, mutect2, varscan2
- IFT122 | c.546C>T p.I182= | Silent (SNP) | VAF 29/155 reads (19%) | catalogued as COSV99959438; called by muse, mutect2, varscan2
- IGKV1D-13 | c.288C>A p.T96= | Silent (SNP) | VAF 35/80 reads (44%) | called by mutect2, varscan2
- IGKV2D-28 | c.351A>G p.L117= | Silent (SNP) | VAF 123/172 reads (72%) | catalogued as COSV101494561, COSV101494564; called by muse, mutect2, varscan2
- IGSF5 | c.570T>C p.V190= | Silent (SNP) | VAF 36/85 reads (42%) | catalogued as COSV101012075; called by muse, mutect2, varscan2
- IKZF2 | c.417C>T p.P139= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV59577129; called by muse, mutect2, varscan2
- IPO13 | c.339C>T p.A113= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV100961238; called by muse, mutect2, varscan2
- KCNJ5 | c.888G>A p.Q296= | Silent (SNP) | VAF 65/200 reads (33%) | catalogued as COSV100610704; called by muse, mutect2, varscan2
- KLHL4 | c.180C>T p.N60= | Silent (SNP) | VAF 27/40 reads (68%) | catalogued as rs750868540, COSV100909722; called by muse, mutect2, varscan2
- KRT13 | c.594G>C p.L198= | Silent (SNP) | VAF 38/95 reads (40%) | catalogued as COSV99877401; called by muse, mutect2, varscan2
- KRTAP4-2 | c.144G>C p.P48= | Silent (SNP) | VAF 34/134 reads (25%) | catalogued as rs201015994, COSV66658909; called by muse, varscan2
- LINGO4 | c.705C>A p.I235= | Silent (SNP) | VAF 27/114 reads (24%) | catalogued as COSV100561973; called by muse, mutect2, varscan2
- LRFN1 | c.933G>T p.V311= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV99953024; called by muse, mutect2, varscan2
- LRIT1 | c.1371T>C p.T457= | Silent (SNP) | VAF 14/25 reads (56%) | catalogued as rs755436852, COSV100928099; called by muse, mutect2, varscan2
- LRIT2 | c.786C>A p.I262= | Silent (SNP) | VAF 36/73 reads (49%) | catalogued as COSV100258974; called by muse, mutect2, varscan2
- LRIT3 | c.1677G>A p.V559= | Silent (SNP) | VAF 36/109 reads (33%) | catalogued as rs762638752, COSV100016188; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRP1B | c.2223T>C p.P741= | Silent (SNP) | VAF 29/82 reads (35%) | catalogued as COSV101257788; called by muse, mutect2, varscan2
- MAGEB18 | c.975T>C p.A325= | Silent (SNP) | VAF 8/10 reads (80%) | catalogued as COSV100305499; called by muse, mutect2, varscan2
- MAGEC3 | c.1320T>C p.A440= | Silent (SNP) | VAF 22/40 reads (55%) | catalogued as COSV100025573; called by muse, mutect2, varscan2
- MAPT | c.210A>T p.P70= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as COSV99290672; called by muse, mutect2, varscan2
- MAST1 | c.594C>G p.R198= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV99263101; called by muse, mutect2
- MFNG | c.117C>A p.P39= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as COSV99325042; called by muse, mutect2, varscan2
- MMRN1 | c.960G>A p.V320= | Silent (SNP) | VAF 39/109 reads (36%) | catalogued as COSV99307274; called by muse, mutect2, varscan2
- MOCS1 | c.387G>A p.P129= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs547995191, COSV57937526; called by muse, mutect2, varscan2
- MUC17 | c.6516G>T p.V2172= | Silent (SNP) | VAF 224/525 reads (43%) | catalogued as COSV100073764; called by muse, mutect2, varscan2
- MYCBPAP | c.33A>G p.R11= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as COSV100088370; called by muse, mutect2, varscan2
- MYH13 | c.2788T>C p.L930= | Silent (SNP) | VAF 90/115 reads (78%) | catalogued as rs1283587614, COSV99354313; called by muse, mutect2, varscan2
- MYO15A | c.1611G>T p.P537= | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as COSV52760692, COSV99233195; called by muse, mutect2, varscan2
- NIPBL | c.3924G>A p.A1308= | Silent (SNP) | VAF 86/136 reads (63%) | catalogued as rs367925827, COSV99243209; called by muse, mutect2, varscan2
- NSUN2 | c.397C>A p.R133= | Silent (SNP) | VAF 38/58 reads (66%) | catalogued as rs1333817754, COSV52955809, COSV52957008, COSV99243249; called by muse, mutect2, varscan2
- NYAP2 | c.1311C>A p.P437= | Silent (SNP) | VAF 27/54 reads (50%) | catalogued as COSV99797064; called by muse, mutect2, varscan2
- OR10H1 | c.144C>T p.T48= | Silent (SNP) | VAF 52/166 reads (31%) | catalogued as rs142314142; called by muse, mutect2, varscan2
- OR1S1 | c.813G>T p.V271= | Silent (SNP) | VAF 32/122 reads (26%) | catalogued as COSV100515420; called by muse, mutect2, varscan2
- OR2G2 | c.906G>C p.G302= | Silent (SNP) | VAF 37/219 reads (17%) | catalogued as COSV100189781; called by muse, mutect2, varscan2
- OR52E6 | c.780C>T p.F260= | Silent (SNP) | VAF 23/43 reads (53%) | catalogued as COSV100259377, COSV61431271; called by muse, mutect2, varscan2
- OR5AS1 | c.930T>C p.Y310= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as rs753535718, COSV100546305; called by muse, mutect2, varscan2
- PCDH17 | c.2067C>A p.P689= | Silent (SNP) | VAF 55/137 reads (40%) | catalogued as COSV100931712; called by muse, mutect2, varscan2
- PCDH17 | c.2428C>A p.R810= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs147572809, COSV100931714; called by muse, mutect2, varscan2
- PCDHGA7 | c.2146C>T p.L716= | Silent (SNP) | VAF 46/83 reads (55%) | catalogued as rs769354835, COSV54051605; called by muse, mutect2, varscan2
- PEX5 | c.1293G>A p.R431= (on ENST00000420616; = p.R423= on NM_000319.5) | Silent (SNP) | VAF 48/130 reads (37%) | catalogued as rs1242502801, COSV99871021; called by muse, mutect2, varscan2
- PIAS2 | c.1857A>C p.S619= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as COSV101286507; called by muse, mutect2, varscan2
- PLPPR5 | c.477T>C p.Y159= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as COSV99587431; called by muse, mutect2, varscan2
- PLXNA4 | c.5610C>T p.H1870= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as rs550735539, COSV100323719; called by muse, mutect2, varscan2
- PMEPA1 | c.177G>T p.T59= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV55696029, COSV99671852; called by muse, mutect2, varscan2
- PROC | c.1180C>A p.R394= | Silent (SNP) | VAF 66/198 reads (33%) | catalogued as CM941191, COSV52167915, COSV99300804; called by muse, mutect2, varscan2
- PRTG | c.711T>A p.I237= | Silent (SNP) | VAF 65/190 reads (34%) | catalogued as COSV101221406; called by muse, mutect2, varscan2
- PYCR3 | c.780C>G p.A260= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as COSV55307430, COSV99643513; called by muse, varscan2
- RASL10B | c.504G>A p.L168= | Silent (SNP) | VAF 21/82 reads (26%) | called by muse, mutect2, varscan2
- RBFOX1 | c.291G>C p.P97= | Silent (SNP) | VAF 42/135 reads (31%) | catalogued as COSV100301854, COSV60954487; called by muse, mutect2, varscan2
- RBFOX1 | c.540G>T p.V180= | Silent (SNP) | VAF 49/168 reads (29%) | catalogued as COSV100301857; called by muse, mutect2, varscan2
- RCAN2 | c.591C>T p.N197= | Silent (SNP) | VAF 70/181 reads (39%) | catalogued as rs972133613, COSV100149912, COSV57818158; called by muse, mutect2, varscan2
- RELN | c.3240G>A p.E1080= | Silent (SNP) | VAF 46/125 reads (37%) | catalogued as COSV100633987; called by muse, mutect2, varscan2
- RNASEL | c.411G>A p.K137= | Silent (SNP) | VAF 35/59 reads (59%) | catalogued as COSV100842607; called by muse, mutect2, varscan2
- SALL3 | c.2136C>T p.C712= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs1233975579, COSV73306578; called by muse, mutect2, varscan2
- SCG5 | c.321T>C p.F107= | Silent (SNP) | VAF 61/234 reads (26%) | catalogued as rs1567084814, COSV100276810; called by muse, mutect2, varscan2
- SCN7A | c.3222C>A p.I1074= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV101313258; called by muse, varscan2
- SELE | c.1497G>T p.P499= | Silent (SNP) | VAF 14/82 reads (17%) | called by muse, mutect2, varscan2
- SERTAD2 | c.78C>T p.D26= | Silent (SNP) | VAF 71/226 reads (31%) | catalogued as rs759031359, COSV100512209; called by muse, mutect2, varscan2
- SLC22A2 | c.700C>A p.R234= | Silent (SNP) | VAF 52/170 reads (31%) | catalogued as COSV100870994; called by muse, mutect2, varscan2
- SLC2A2 | c.225C>T p.N75= | Silent (SNP) | VAF 121/182 reads (66%) | catalogued as COSV58584703; called by muse, mutect2, varscan2
- SLITRK3 | c.1794G>A p.T598= | Silent (SNP) | VAF 49/93 reads (53%) | catalogued as rs1053030805, COSV99579424; called by muse, mutect2, varscan2
- SPATA31A1 | c.3918C>A p.P1306= | Silent (SNP) | VAF 106/245 reads (43%) | called by muse, mutect2, varscan2
- STARD8 | c.1542C>A p.I514= | Silent (SNP) | VAF 23/31 reads (74%) | catalogued as COSV99367023; called by muse, mutect2, varscan2
- SV2B | c.1929C>A p.T643= | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as COSV100370726, COSV100371025; called by muse, mutect2, varscan2
- SYNRG | c.960A>G p.K320= | Silent (SNP) | VAF 48/141 reads (34%) | called by muse, mutect2, varscan2
- TERT | c.2320C>A p.R774= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs770066110, COSV57198530, COSV99718890; called by mutect2, varscan2
- TMEM132D | c.3210G>A p.E1070= | Silent (SNP) | VAF 45/145 reads (31%) | catalogued as COSV101242902; called by muse, mutect2, varscan2
- TSHZ3 | c.1470G>A p.K490= | Silent (SNP) | VAF 62/335 reads (19%) | catalogued as COSV99551840; called by muse, mutect2, varscan2
- TTN | c.68367G>A p.L22789= (on ENST00000591111; = p.L15365= on NM_003319.4) | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as COSV100617433; called by muse, mutect2, varscan2
- TXNDC2 | c.1101C>T p.I367= (on ENST00000306084 / NM_001098529.2; = p.I300= on NM_032243.6) | Silent (SNP) | VAF 151/292 reads (52%) | catalogued as rs371765106; called by muse, mutect2, varscan2
- UGGT1 | c.1401T>C p.D467= | Silent (SNP) | VAF 86/221 reads (39%) | catalogued as rs1190036928, COSV99390822; called by muse, mutect2, varscan2
- UGT2B15 | c.198C>T p.A66= | Silent (SNP) | VAF 111/353 reads (31%) | catalogued as COSV100592344; called by muse, mutect2, varscan2
- VAV3 | c.240G>T p.T80= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as rs750871358, COSV100894535; called by muse, mutect2, varscan2
- VCAN | c.6081C>T p.P2027= | Silent (SNP) | VAF 32/51 reads (63%) | catalogued as COSV99426161; called by muse, mutect2, varscan2
- WDR72 | c.1677T>G p.P559= | Silent (SNP) | VAF 59/233 reads (25%) | catalogued as COSV100854601; called by muse, mutect2, varscan2
- WIPF1 | c.1500C>T p.P500= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV99768821; called by muse, mutect2, varscan2
- WNK2 | c.2628T>C p.I876= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as COSV99942974; called by muse, mutect2, varscan2
- XIRP2 | c.1719G>T p.S573= (on ENST00000628543; = p.S748= on NM_152381.6) | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as COSV54720807, COSV99743893; called by muse, mutect2, varscan2
- XIRP2 | c.1852C>A p.R618= (on ENST00000628543; = p.R793= on NM_152381.6) | Silent (SNP) | VAF 33/101 reads (33%) | catalogued as COSV99743895; called by muse, mutect2, varscan2
- ZMAT4 | c.456C>A p.A152= | Silent (SNP) | VAF 69/296 reads (23%) | catalogued as COSV99910270; called by muse, mutect2, varscan2
- ZNF257 | c.96G>T p.V32= | Silent (SNP) | VAF 78/220 reads (35%) | catalogued as COSV101448110; called by muse, mutect2, varscan2
- ZNF560 | c.1374G>A p.K458= | Silent (SNP) | VAF 83/242 reads (34%) | catalogued as COSV100038700; called by muse, mutect2, varscan2
- ZNF804B | c.1797G>A p.E599= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV60826129; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499121 T>A | 5'Flank (SNP) | VAF 26/93 reads (28%) | catalogued as rs780455952; called by muse, mutect2, varscan2
- C21orf62 | c.*32T>C | 3'UTR (SNP) | VAF 26/77 reads (34%) | catalogued as rs774246169, COSV101212314; called by muse, mutect2, varscan2
- CBFA2T2 | c.*5del | 3'UTR (DEL) | VAF 35/142 reads (25%) | called by mutect2, pindel, varscan2
- CCDC140 | n.491G>T | RNA (SNP) | VAF 19/37 reads (51%) | catalogued as COSV54674785, COSV99735141; called by muse, mutect2, varscan2
- DCHS2 | n.701T>G | RNA (SNP) | VAF 19/48 reads (40%) | catalogued as COSV100252143; called by muse, mutect2, varscan2
- DLG2 | c.205-65598C>G | Intron (SNP) | VAF 29/77 reads (38%) | catalogued as COSV99716790; called by muse, mutect2, varscan2
- NKX2-1 | chr14:36520066 G>A | 5'Flank (SNP) | VAF 20/52 reads (38%) | catalogued as COSV100701938; called by muse, mutect2, varscan2
- PSG5 | c.431-2976A>T | Intron (SNP) | VAF 116/309 reads (38%) | catalogued as COSV61655540; called by muse, mutect2
- SSPOP | n.2920C>A | RNA (SNP) | VAF 53/114 reads (46%) | catalogued as COSV100022614; called by muse, mutect2, varscan2
- SSPOP | n.2921T>A | RNA (SNP) | VAF 53/115 reads (46%) | catalogued as COSV100022616; called by muse, mutect2, varscan2
- SSPOP | n.15162G>C | RNA (SNP) | VAF 17/45 reads (38%) | catalogued as COSV100947522; called by muse, mutect2, varscan2
- TTN | c.34264+5685G>A | Intron (SNP) | VAF 80/159 reads (50%) | catalogued as rs370960330; ClinVar: likely benign; called by muse, mutect2, varscan2
- TUBB7P | n.767A>C | RNA (SNP) | VAF 21/50 reads (42%) | called by muse, mutect2, varscan2
- ZNF99 | c.*847G>T | 3'UTR (SNP) | VAF 16/47 reads (34%) | catalogued as COSV101233853; called by muse, mutect2, varscan2
